Somatic mutation profile of tumor specimen TCGA-06-0185-01A (aliquot TCGA-06-0185-01A-01W-0254-08) from TCGA case TCGA-06-0185, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.5 years (19,923 days).
Specimen TCGA-06-0185-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74c8bae2-0cad-42c9-bc24-0f5591d45256.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0185-10B (Blood Derived Normal), aliquot TCGA-06-0185-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3264085f-1be7-4919-bfb2-e41ef256286c

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C9orf131 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV56609793; called by muse, mutect2
- CFAP20DC | c.1454G>A p.R485Q (on ENST00000482387 / NM_001351530.2; = p.R360Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs571045260, COSV55916637; called by muse, mutect2, varscan2
- DDR2 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV63369520; called by muse, mutect2, varscan2
- DYNC1I1 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as rs201114371, COSV61456326; called by muse, mutect2, varscan2
- HMCN1 | c.4474A>T p.K1492* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV54880137; called by muse, mutect2, varscan2
- HOOK1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64618107; called by muse, mutect2, varscan2
- JADE1 | c.448T>A p.W150R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56904456; called by muse, varscan2
- KMT2C | c.4906A>C p.T1636P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs80039782; called by muse, mutect2
- RBMXL1 | c.980A>T p.Y327F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as COSV53098855; called by muse, mutect2
- STAT1 | c.602A>T p.K201M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV61189675; called by muse, mutect2, varscan2
- TMTC1 | c.1058G>A p.R353Q (on ENST00000539277 / NM_001193451.2; = p.R245Q on NM_175861.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375595309; called by muse, mutect2, varscan2
- TRIM59 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV59086504; called by muse, mutect2, varscan2
- PPP1R9A | c.1649+2T>G p.X550_splice | Splice Site (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2
- ADAM9 | c.351G>A p.R117= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV65946586; called by muse, mutect2, varscan2
- USH2A | c.3696G>A p.L1232= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV56332402; called by muse, mutect2, varscan2
